Surgical pathology report (de-identified scan), TCGA case TCGA-06-0210, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0210-02A (Recurrent Tumor).

[page 1 of 2]
PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX: F DOB:

SURGERY DATE:

RECEIVE DATE:

PHYSICIAN:

UPDATED REPORT - SEE ADDENDUM DIAGNOSIS.

PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSIES: MALIGNANT
GLIOMA WITH ASTROBLASTOMA PATTERN.
SEE MICROSCOPIC DESCRIPTION AND COMMENT.

ADDENDUM DIAGNOSIS: MIB-1 LABELLING INDEX 23%.

Operation/Specimen: Right temporal lobe.

Clinical History and Pre-Op Dx: year old woman with recurrent glioma.

GROSS PATHOLOGY:

A. Received fresh, four fragments, 0.7 cm across the largest one.
Tan-gray, semifirm. In total 1-3.

INTRAOPERATIVE CONSULTATION: Frozen section diagnosis:
Brain, right temporal: High histological grade glioma, consistent with
astroblastoma multiforme.

B. Received fresh, two fragments, 0.3 and 1.3 cm across, respectively.
Tan-pink, soft and glassy. In total 4 and 5.

MICROSCOPIC: A. Portions of a neoplastic proliferation of glial cells
with clear features of anaplasia including pleomorphic and
hyperchromatic nuclei, mitoses and endothelial vascular proliferation.
Perivascular astroblastomatous pseudorosettes are present.

B. Portions of a neoplastic proliferation of glial cells with
morphological features similar to those described for part A. Focal
areas of necrosis are observed.

COMMENT: The lesion is a high histological grade glial neoplasm that
has a prominent astroblastic pattern. This feature is not uncommonly
seen in glioblastomas multiforme.

Cont'd...

ICD-0-3 Neuror

Glioblastoma, multiforme 9440/3

Site: Temporal lobe C71-2

*fw
2/2/15*

[page 2 of 2]
A MIB-1 labelling index will be performed and an addendum report will follow.

ADDENDUM REPORT

SPECIAL STAIN: A MIB-I immunoperoxidase stain was performed on block #3.

A MIB-1 labelling index of 23% was determined.

TISSUE COMMITTEE CODE:

BILLING CODES:

Source: NCI Genomic Data Commons file 90ef9904-b52c-418b-92be-eb8e07953032 (TCGA-06-0210.5617D8A4-BB27-4643-A3FD-8DDCF659CB3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).